Surgical pathology report (de-identified scan), TCGA case TCGA-SH-A9CT, project TCGA-MESO (Mesothelioma), tissue source site Papworth Hospital, specimen TCGA-SH-A9CT-01A (Primary Tumor).

HISTOPATHOLOGY REPORT

Sex: M

Date Collected:

Date Received:

Date Printed:

Copy To:

SPECIMEN DETAILS

Specimen A Parietal pleura

Specimen B Parietal pleura tumour

CLINICAL INFORMATION

Epithelioid mesothelioma T2 H0 M0

*ICD O 3
Mesothelioma, epithelial, malignant 9052/3
Site: Parietal pleura C38.4
9052/3/14*

MACROSCOPIC DESCRIPTION

Specimen A Parietal pleura

An irregular piece of cream coloured tumour measuring 8 x 3.5 x 2 cm

4 in 4 + reserve.

Specimen B Parietal pleura tumour

Several pieces of white, firm tumour tissue with attached adipose tissue and adherent clot, in aggregate measuring 18 x 16 x up to 3 cm. Some of the pieces include overlying pleura.

4 x representative sections + reserve.

MICROSCOPIC REPORT

Specimens A & B Parietal pleura tumour

Samples from both specimens reveal thickened pleura, extensively infiltrated by epithelioid tumour with a predominantly papillary architecture. The epithelioid tumour cells exhibit a moderate degree of pleomorphism and possess vesicular nuclei with small nucleoli and a moderate amount of eosinophilic cytoplasm. Focal areas of tumour necrosis are present. Some of the sections include a small amount of adherent lung parenchyma, which in areas shows reactive changes with organising pneumonia. Focally there is evidence of infiltration of the visceral pleura.

Immunohistochemistry - The tumour is positive for MNF116 and calretinin (cytoplasmic and variable nuclear staining), shows patchy staining for WT1, focal weak staining for CK5/6 and diffuse membranous positivity for EMA. Very focal staining for BerEP4 is noted, but most of the tumour is negative for this marker, as well as TTF1.

The appearances are those of epithelioid malignant mesothelioma.

Reporting Pathologist:

Authorising Pathologist:

Lab No:

Source: NCI Genomic Data Commons file 16623845-a38a-4039-ade6-64e0e4bbdd7e (TCGA-SH-A9CT.D7747749-3C50-4563-A68D-AE29D0C22749.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).